Gene-level copy-number profile of tumor specimen TCGA-KP-A3W4-01A from TCGA case TCGA-KP-A3W4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.5 years (23,200 days).
Specimen TCGA-KP-A3W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.6cdf4839-6b21-496d-8734-0bd34fcf9d9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KP-A3W4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cdc67cbe-d65c-40b3-8382-d6e606b91ebe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,335; copy number 2: 48,332; copy number 3: 2,311; copy number 4: 300; copy number 5: 483; copy number 6: 3; copy number 8: 3; copy number 9: 22; copy number 29: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KP-A3W4-01A-11D-A227-01): tumor purity 0.71, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 533 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,003,022–169,038,416, 1 gene, copy number 6: LINC01997.
- chr4:7,758,714–7,940,296, 3 genes, copy number 5 (within-gene range 3–5): AFAP1, AC112254.1, AC097381.1.
- chr4:8,005,301–8,023,126, 2 genes, copy number 5: MIR95, AC097381.3.
- chr7:139,777,051–140,020,325, 1 gene, copy number 6 (within-gene range 3–6): TBXAS1.
- chr8:52,110,839–52,460,959, 1 gene, copy number 8 (within-gene range 2–9): ST18.
- chr8:52,294,455–85,177,062, 486 genes, copy number 5–9 (broad region; genes not listed).
- chr8:96,645,242–97,358,478, 6 genes, copy number 9 (within-gene range 4–10): CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H.
- chr8:139,508,701–139,508,971, 1 gene, copy number 6: AC090093.1.
- chr14:76,921,840–77,086,457, 10 genes, copy number 5 (within-gene range 2–5): AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289.
- chr17:39,461,486–39,944,734, 22 genes, copy number 29 (within-gene range 3–29): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C.

Autosomal genes at a single copy (total copy number 1): 7,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
